TCGA case TCGA-DQ-7596 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Tonsil; Tissue source site: University Of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0f25d7fd-fc7c-4563-a8bd-80b5e0c32ea2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 48 years; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C09.9; Tissue or organ of origin: Tonsil, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 48.9 years (17,846 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N2a; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Days to treatment start: 13 days; Days to treatment end: 60 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 19 days; Days to treatment end: 69 days; Treatment dose: 70 Gy; Treatment outcome: Partial Response; Number of fractions: 35; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Pemetrexed Disodium; Days to treatment start: 203 days; Days to treatment end: 266 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Cure; Days to treatment end: 69 days; Treatment outcome: Persistent Disease; Chemo concurrent to radiation: Yes.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Lymph nodes of head, face and neck. Age at diagnosis: 49.2 years (17,983 days); Days to diagnosis: 137 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 152 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 152 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 137 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph nodes of head, face and neck; Days to recurrence: 137 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 340 days; Disease response: Tumor Free.
- Days to follow up: 1,265 days (3.5 years); Disease response: Tumor Free.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 3; Alcohol days per week: 1.
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DQ-7596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.3; Shortest dimension: 0.3.
  Slide TCGA-DQ-7596-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 65; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 25.
- Sample TCGA-DQ-7596-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DQ-7596-10D: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph node neck dissection indicator: No; Tobacco smoking history indicator: 1; Alcohol consumption frequency: 1.
- Drug treatment 1: Pharmaceutical therapy drug name: erbitux.
- Drug treatment 2: Pharmaceutical therapy drug name: alimta.
- Follow-up form 1: New tumor event surgery: Yes; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; New tumor event site: Cervical Lymph Nodes; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Stable Disease; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Concurrent Chemotherapy; Definitive treatment evidence disease after: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,265 days; disease-specific survival: no event (censored), 1,265 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 137 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DQ-7596-01A-11D-2228-01): tumor purity 0.45, ploidy 2.1, whole-genome doublings 0.
